TCGA case TCGA-AC-A6IV — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e11c5ec-c15a-48d4-85ac-b7b08a9ed827

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating lobular mixed with other types of carcinoma: ICD-O-3 morphology code: 8524/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 48.0 years (17,521 days); Year of diagnosis: 2012; Method of diagnosis: Core Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 1; Micrometastasis present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (2 entries)
- Days to follow up: 36 days; Disease response: Tumor Free.
- Days to follow up: 568 days (1.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ESR1 (IHC): Positive; Test value range: 90-99%.
- PGR (IHC): Positive; Test value range: 60-69%.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AC-A6IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 110 mg.
  Slide TCGA-AC-A6IV-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 60; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AC-A6IV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AC-A6IV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Micromet detection by IHC: Yes; Her2 IHC score: 2+; Margin status: Negative; Method initial path diagnosis: Core needle biopsy; Prospective collection: Yes; Retrospective collection: No; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 568 days; disease-specific survival: no event (censored), 568 days; disease-free interval: no event (censored), 568 days; progression-free interval: no event (censored), 568 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AC-A6IV-01A-12D-A33D-01): tumor purity 0.3, ploidy 2.03, whole-genome doublings 0.
